Somatic mutation profile of tumor specimen TCGA-AK-3465-01A (aliquot TCGA-AK-3465-01A-01D-0966-08) from TCGA case TCGA-AK-3465, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 71.8 years (26,232 days).
Specimen TCGA-AK-3465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2211db97-9780-438d-b265-7314c0effe67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3465-10A (Blood Derived Normal), aliquot TCGA-AK-3465-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02fb4a0a-412a-46f9-b100-be74dc52dd07

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs74821926, CM870084, CM890279, CM910022, COSV55735814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASCC2 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57072516; called by muse, mutect2, varscan2
- ATP1A3 | c.251C>T p.T84M (on ENST00000545399 / NM_001256214.2; = p.T71M on NM_152296.5) | Missense Mutation (SNP) | VAF 101/244 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57485231; called by muse, mutect2, varscan2
- C1QC | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65889349; called by muse, varscan2
- CAAP1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61700383; called by muse, mutect2, varscan2
- ELAPOR1 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV64040109; called by muse, mutect2
- FNIP1 | c.1480del p.A494Qfs*26 | Frame Shift Del (DEL) | VAF 94/296 reads (32%) | catalogued as COSV57195537; called by mutect2, pindel, varscan2
- GTF3C2 | c.1130T>C p.F377S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53125401; called by muse, mutect2
- IL12RB1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as rs774754664, COSV74045445; called by muse, mutect2
- ITIH2 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as rs142420238; called by muse, mutect2, varscan2
- LRRC14 | c.1121_1124del p.E374Vfs*15 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | catalogued as rs760735477; called by mutect2, pindel, varscan2
- OR6Q1 | c.239T>G p.V80G | Missense Mutation (SNP) | VAF 172/233 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV56932513; called by muse, mutect2, varscan2
- PCDHGB6 | c.2126T>A p.L709Q | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53914164; called by muse, mutect2, varscan2
- PLXNA4 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs143690954, COSV58111460; called by muse, mutect2, varscan2
- PRPF40B | c.143C>T p.A48V (on ENST00000380281; = p.A42V on NM_012272.3) | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs149751647; called by mutect2, varscan2
- PRR23B | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1025038813, COSV61493298; called by muse, varscan2
- RADIL | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs765026527, COSV68199821; called by muse, mutect2, varscan2
- SAMD4B | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV58750516; called by muse, mutect2, varscan2
- SIPA1L3 | c.5093C>T p.P1698L | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as rs765717001, COSV55910444; called by muse, mutect2, varscan2
- SLC45A1 | c.1832A>G p.Y611C | Missense Mutation (SNP) | VAF 118/154 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754751877, COSV57093663; called by muse, mutect2, varscan2
- WDR27 | c.2130G>T p.R710S | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs749053028, COSV61205454; called by muse, mutect2, varscan2
- BBOF1 | c.777_781del p.L259Ffs*8 | Frame Shift Del (DEL) | VAF 47/109 reads (43%) | called by pindel, varscan2
- FCGBP | c.7997C>A p.S2666Y | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, varscan2
- CIITA | c.1962C>T p.P654= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs769190445, COSV60854939, COSV60859158, COSV60859574; called by muse, mutect2, varscan2
- ELFN2 | c.708C>T p.N236= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs149957183; called by muse, mutect2, varscan2
- FCGBP | c.7998C>G p.S2666= | Silent (SNP) | VAF 46/373 reads (12%) | called by muse, mutect2, varscan2
- RORC | c.48G>T p.L16= | Silent (SNP) | VAF 8/161 reads (5%) | catalogued as COSV59092104; called by muse, mutect2
- SCYL1 | c.372C>T p.I124= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs773893669, COSV54211036; called by muse, mutect2
- SSTR5 | c.459G>A p.P153= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs141899937, COSV53512181; called by muse, mutect2, varscan2
- TMC2 | c.1668C>T p.N556= | Silent (SNP) | VAF 140/308 reads (45%) | catalogued as rs144876435; called by muse, mutect2, varscan2
